Somatic mutation profile of tumor specimen C3N-00682-54 (aliquot CPT0383920001) from CPTAC case C3N-00682, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 69.1 years (25,252 days).
Specimen C3N-00682-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f855385-010f-4af1-bc39-3899de2acece.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00682-50 (Buccal Cell Normal), aliquot CPT0384020001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdf2f275-3bb4-453d-bbbc-fbc8f2886fad

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Frame Shift Ins 2, Nonsense Mutation 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/58 reads (34%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ARHGEF28 | c.3530A>G p.N1177S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs1376499733; called by muse, mutect2, varscan2
- CCER2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778686851; called by muse, varscan2
- CCNJL | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as rs777541658; called by muse, varscan2
- MYC | c.176C>A p.P59Q (on ENST00000377970; = p.P74Q on NM_002467.6) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368162, COSV52368882, COSV52375206; called by muse, varscan2
- THBS2 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs758612535; called by mutect2, varscan2
- BTBD7 | c.2965A>C p.K989Q | Missense Mutation (SNP) | VAF 150/321 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- STAG2 | c.624dup p.D209* | Frame Shift Ins (INS) | VAF 61/85 reads (72%) | called by mutect2, pindel, varscan2
- SYNPR | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB7A | c.532_535del p.A178Pfs*39 | Frame Shift Del (DEL) | VAF 33/134 reads (25%) | called by mutect2, pindel, varscan2
- TRIM77 | c.48G>A p.S16= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1487850198, COSV101242258; called by muse, varscan2
